Somatic mutation profile of tumor specimen ALCH-B2DO-TTP1-A (aliquot ALCH-B2DO-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2DO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.5 years (21,360 days).
Specimen ALCH-B2DO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8de7296e-a89c-464c-b2f0-f194dc31b7cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2DO-NB1-A (Blood Derived Normal), aliquot ALCH-B2DO-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c54a382-fbb5-4769-ad5d-7c502c4f05a8

The open-access MAF lists 370 somatic variants for this specimen: 249 protein-altering or splice-affecting, 70 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 70, Intron 28, Nonsense Mutation 18, RNA 9, Frame Shift Del 8, 5'Flank 6, 5'UTR 5, Splice Site 3, Splice Region 3, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.458-1G>T p.X153_splice | Splice Site (SNP) | VAF 53/496 reads (11%) | hotspot (GDC flag); catalogued as CS127044, COSV58686546, COSV58687455, COSV58704542; called by muse, mutect2, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 33/336 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ADGRB3 | c.2599A>G p.R867G | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.444); catalogued as rs1415869667; called by muse, mutect2
- AKR1D1 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 16/294 reads (5%) | catalogued as COSV54335901; called by muse, mutect2
- ATF7IP | c.3197C>G p.T1066S | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV53770046; called by muse, mutect2, varscan2
- CACNA1E | c.5866G>A p.D1956N | Missense Mutation (SNP) | VAF 8/255 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs1033770342, COSV100701833, COSV100702676; called by muse, mutect2
- CCDC149 | c.1261G>A p.A421T (on ENST00000635206 / NM_001330643.2; = p.A410T on NM_173463.5) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.17); catalogued as rs1047666416; called by muse, mutect2, varscan2
- CCDC170 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 28/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53336291; called by muse, mutect2
- CDH18 | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 14/410 reads (3%) | catalogued as COSV99932746; called by muse, mutect2
- CDX4 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100999141, COSV65171674; called by muse, mutect2
- CES1 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828767; called by muse, mutect2
- CFHR5 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201808624, COSV99888045; called by muse, mutect2, varscan2
- CIT | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV55872356, COSV55882946; called by muse, varscan2
- CLEC14A | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs1169789088; called by muse, mutect2, varscan2
- CLSTN2 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1333814424, COSV71720331; called by muse, mutect2
- COG5 | c.1814C>G p.P605R (on ENST00000347053 / NM_001379512.1; = p.P626R on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV51748854; called by muse, mutect2
- CRISP2 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV59257021; called by muse, mutect2
- CTNNA3 | c.2224G>A p.G742R | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101041161; called by muse, mutect2
- CXorf21 | c.22A>T p.S8C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.634); catalogued as COSV66762668; called by muse, mutect2, varscan2
- DCC | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV59113109; called by muse, mutect2
- DPF3 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 29/152 reads (19%) | catalogued as COSV63498695; called by muse, mutect2, varscan2
- ERMN | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68075280, COSV68075322; called by muse, varscan2
- ESCO1 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99332308; called by muse, mutect2
- GCM2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 23/435 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146812948, COSV101069624; called by muse, mutect2
- GPM6A | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as rs1322947726, COSV54564075; called by muse, mutect2
- GRXCR1 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV67671782; called by muse, mutect2
- HTR1A | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 18/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60500810, COSV60503470; called by muse, mutect2
- IGHG4 | c.296-2A>G p.X99_splice | Splice Site (SNP) | VAF 27/219 reads (12%) | catalogued as rs1301936266; called by muse, mutect2, varscan2
- IGKV1D-43 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs1301223848; called by muse, mutect2
- IGLL5 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs571956646; called by muse, mutect2
- IGSF21 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.854); catalogued as rs200809740, COSV52131170, COSV52138833; called by muse, mutect2, varscan2
- KCNK9 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 128/643 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.884); catalogued as rs774633097; called by muse, mutect2, varscan2
- LEPR | c.3193G>T p.G1065* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV62748695; called by muse, mutect2, varscan2
- LHX8 | c.1018C>G p.L340V | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV99633351; called by muse, mutect2
- LILRB5 | c.896A>G p.H299R | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV60255924; called by muse, mutect2, varscan2
- LRP1B | c.10397C>A p.S3466* | Nonsense Mutation (SNP) | VAF 10/180 reads (6%) | catalogued as COSV101259952; called by muse, mutect2
- MUC5B | c.13045T>C p.S4349P | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.526); catalogued as COSV71595467; called by muse, mutect2
- NDUFAF5 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1433339359; called by muse, mutect2, varscan2
- NFATC2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs1568726068, COSV65353091; called by muse, mutect2
- NLRX1 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 22/231 reads (10%) | catalogued as COSV52709056; called by muse, mutect2
- NNT | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV52931069; called by muse, mutect2
- OR11L1 | c.107G>T p.C36F | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63313797, COSV63316077; called by muse, mutect2, varscan2
- OR2A25 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV68717067; called by muse, mutect2
- OR2T34 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.342); catalogued as COSV100170205; called by muse, mutect2, varscan2
- OTOGL | c.750G>T p.K250N (on ENST00000547103; = p.K241N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV72007413; called by muse, mutect2
- PARD3B | c.1214A>G p.H405R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1300730659; called by muse, mutect2
- PCDHA13 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 16/149 reads (11%) | catalogued as COSV56476248; called by muse, mutect2, varscan2
- PDYN | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 18/617 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.418); catalogued as rs1423090274, COSV54102687; called by muse, mutect2
- PFKM | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368997884; called by muse, mutect2
- POLG | c.2437G>T p.V813L | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99037503; called by muse, mutect2
- POLG | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1176955778; called by muse, mutect2
- POMT2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99836141; called by muse, mutect2
- PRORP | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs749697011; called by muse, mutect2, varscan2
- RANBP2 | c.6260A>G p.H2087R | Missense Mutation (SNP) | VAF 64/916 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99312358; called by muse, mutect2
- RASGRP2 | c.1290G>T p.M430I | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100818237, COSV62449200; called by muse, mutect2
- RTL4 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV61206166; called by muse, mutect2
- RYR1 | c.6407G>A p.R2136H | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs530885842, COSV62103633; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- SCN2A | c.5621C>A p.A1874D | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV51858836; called by muse, mutect2
- SFMBT2 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774566967, COSV62811349; called by mutect2, varscan2
- SFTPA2 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.024); catalogued as COSV64882924; called by muse, mutect2
- SLC6A5 | c.1737G>T p.M579I | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.898); catalogued as rs1233839969, COSV100117109; called by muse, mutect2
- SPON2 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52054549; called by muse, mutect2, varscan2
- STX2 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55432746; called by muse, mutect2
- TMTC2 | c.1755A>T p.L585F | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as COSV58286050; called by muse, mutect2
- TNNI3 | c.373-3C>A | Splice Region (SNP) | VAF 18/190 reads (9%) | catalogued as rs754577486; called by muse, mutect2
- TPX2 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV55917953; called by muse, mutect2
- TTN | c.28127C>G p.A9376G (on ENST00000591111; = p.A8449G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | PolyPhen benign (0.005); catalogued as COSV100617670; called by muse, mutect2
- WDR38 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs267602127; called by muse, mutect2
- XKR4 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.933); catalogued as COSV59324679, COSV59342013; called by muse, mutect2
- ZFHX4 | c.4861G>T p.A1621S | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs1288812682, COSV50832879; called by muse, mutect2, varscan2
- ZNF772 | c.1146A>C p.E382D | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.949); catalogued as COSV100582778; called by muse, mutect2
- A2ML1 | c.2019C>A p.S673R | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, varscan2
- ABCA13 | c.12342C>A p.Y4114* | Nonsense Mutation (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- ACTC1 | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- ADAMTS20 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADRA1D | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANGEL1 | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKFN1 | c.3039C>G p.D1013E (on ENST00000653862; = p.D866E on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.316); called by muse, mutect2
- ANKFN1 | c.3040T>A p.C1014S (on ENST00000653862; = p.C867S on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.165); called by muse, mutect2
- ANKRD66 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2
- APBB3 | c.845A>G p.D282G (on ENST00000357560 / NM_133173.2; = p.D289G on NM_006051.3) | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- ARHGEF25 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.017); called by muse, mutect2
- ATP10A | c.4130T>G p.M1377R | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); called by muse, mutect2
- ATP10B | c.2988G>T p.L996F | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BFAR | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.276); called by muse, mutect2
- BLOC1S5 | c.36T>A p.C12* | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | called by muse, mutect2, varscan2
- BTBD18 | c.2006C>A p.P669H | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2
- C1orf146 | c.66+2T>A p.X22_splice | Splice Site (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- CA2 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CBLL2 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCR6 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT8L2 | c.1095G>T p.W365C | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2
- CD19 | c.1127del p.P376Rfs*93 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel, varscan2
- CD53 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEACAM3 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 10/360 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.202); called by muse, mutect2
- CEP128 | c.2806+7G>T | Splice Region (SNP) | VAF 23/153 reads (15%) | called by muse, mutect2, varscan2
- CEP162 | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- CLEC3B | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CNKSR2 | c.92T>A p.I31N | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- COIL | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL22A1 | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2
- COL4A1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A1 | c.3833C>T p.P1278L | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2
- COL9A1 | c.1879A>G p.R627G | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); called by muse, mutect2
- CRB1 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRHBP | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- CSMD3 | c.5110C>A p.P1704T (on ENST00000297405 / NM_001363185.1; = p.P1600T on NM_052900.3) | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CSMD3 | c.1592A>T p.E531V (on ENST00000297405 / NM_001363185.1; = p.E427V on NM_052900.3) | Missense Mutation (SNP) | VAF 22/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- CSMD3 | c.1030G>A p.G344S (on ENST00000297405 / NM_001363185.1; = p.V344M on NM_052900.3) | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- CTNNAL1 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2
- DDX24 | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- DISP3 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- DLG2 | c.382G>C p.E128Q (on ENST00000650630 / NM_001351274.2; = p.E91Q on NM_001142699.3) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.038); called by muse, mutect2
- DNAH3 | c.11378C>A p.T3793K | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.175); called by muse, mutect2
- DNAH8 | c.6063G>T p.L2021F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOC2A | c.629A>T p.N210I | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2
- DTNA | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.141); called by muse, mutect2
- DVL1 | c.1534G>T p.G512C (on ENST00000378888 / NM_001330311.2; = p.G487C on NM_004421.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML5 | c.4177del p.T1393Lfs*30 (on ENST00000380664; = p.T1401Lfs*30 on NM_183387.3) | Frame Shift Del (DEL) | VAF 57/339 reads (17%) | called by mutect2, pindel, varscan2
- ESRRG | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAHD2A | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.21); called by muse, mutect2
- FAT3 | c.7462G>A p.G2488R | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2
- FBRSL1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FER1L6 | c.1466C>A p.T489N | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2
- FEZF2 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FOXN3 | c.1097A>T p.Y366F (on ENST00000261302; = p.Y344F on NM_005197.4) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.025); called by muse, varscan2
- FSHR | c.1252A>C p.I418L | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- FYB1 | c.1429A>G p.K477E | Missense Mutation (SNP) | VAF 24/562 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- FYCO1 | c.2451G>T p.E817D | Missense Mutation (SNP) | VAF 42/369 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GABRR3 | c.120A>T p.Q40H | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- GART | c.504C>G p.C168W | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GIGYF2 | c.2170G>T p.E724* | Nonsense Mutation (SNP) | VAF 25/252 reads (10%) | called by muse, mutect2, varscan2
- GPR156 | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.049); called by muse, mutect2
- GRID2 | c.1710G>T p.W570C | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRM5 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- GUCA2B | c.214C>A p.L72M | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HACE1 | c.2482A>G p.R828G | Missense Mutation (SNP) | VAF 26/743 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2
- HOXA2 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 18/503 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.218); called by muse, mutect2
- HS3ST2 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.10749A>C p.E3583D | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2
- HTRA1 | c.1302A>G p.I434M | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL12B | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 50/484 reads (10%) | called by muse, mutect2, varscan2
- IRX2 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.398); called by muse, mutect2
- KCNH7 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- KCNMA1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- KIAA2012 | c.1011C>A p.S337R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.04); called by muse, mutect2
- KLHL24 | c.1634A>T p.K545I | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRBA1 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.5771C>A p.A1924D | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LAMB3 | c.2444G>C p.G815A | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- LCE2B | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 28/179 reads (16%) | called by muse, mutect2, varscan2
- LIPI | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 23/355 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMTK3 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2
- LTF | c.1936T>A p.C646S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2
- MAL | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MCEMP1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.224); called by muse, mutect2
- MCM10 | c.742G>T p.E248* (on ENST00000484800 / NM_182751.3; = p.E247* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MKKS | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 57/538 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- MOG | c.672G>T p.L224F | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.312); called by muse, mutect2
- MRC2 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.382); called by muse, mutect2
- MRPS5 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- MTARC2 | c.760del p.D254Mfs*4 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- NDUFAF5 | c.472A>C p.S158R | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- NLRC5 | c.3191G>T p.R1064L | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, mutect2
- NLRP7 | c.179del p.N60Tfs*8 | Frame Shift Del (DEL) | VAF 28/326 reads (9%) | called by mutect2, pindel
- NRXN1 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NSMAF | c.130A>C p.K44Q | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- OR2AJ1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2B6 | c.704A>G p.Q235R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- OR2C3 | c.296_297del p.V99Gfs*23 | Frame Shift Del (DEL) | VAF 44/348 reads (13%) | called by pindel, varscan2
- OR2M3 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- OR4C6 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.029); called by muse, mutect2
- OR6A2 | c.850G>C p.A284P | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- OR8K3 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- OTOG | c.5888G>T p.G1963V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- OXCT1 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PAGE2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PCDH15 | c.4746G>T p.R1582S | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.071); called by muse, mutect2
- PCDHB1 | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); called by muse, mutect2
- PCMTD2 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- PDE3A | c.2798C>A p.T933N | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PDE9A | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- PDZRN4 | c.2930G>T p.S977I (on ENST00000402685 / NM_001164595.2; = p.S719I on NM_013377.4) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- PEX5L | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2
- PGM5 | c.1333T>C p.Y445H | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.212); called by muse, mutect2
- PI15 | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PIGS | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); called by muse, mutect2
- PLEKHG4 | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- PRAMEF11 | c.1232G>A p.C411Y | Missense Mutation (SNP) | VAF 50/510 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2
- PRRC2B | c.563A>T p.K188M | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- PTAFR | c.69C>A p.S23R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- RASGRF1 | c.2399G>A p.S800N | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- RBBP8NL | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- REC114 | c.86G>C p.C29S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- RNF40 | c.1783G>T p.G595W | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- RTN1 | c.2297C>A p.A766D | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RYR2 | c.2043C>A p.H681Q | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.012); called by muse, mutect2
- SDR42E1 | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SETD1A | c.401A>T p.H134L | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SH3PXD2A | c.803A>T p.E268V (on ENST00000369774 / NM_001365079.1; = p.E240V on NM_014631.2) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SHROOM2 | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SI | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- SKAP1 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- SLC30A1 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SLC5A11 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMARCA4 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- SMC2 | c.1231A>G p.K411E | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2
- SP6 | c.883T>C p.F295L | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA16 | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- SPTBN1 | c.2387A>G p.Y796C | Missense Mutation (SNP) | VAF 9/270 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.076); called by muse, mutect2
- SPX | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- STIM2 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STOX2 | c.1386C>G p.S462R | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.368); called by muse, mutect2
- STRA8 | c.193C>A p.L65M (on ENST00000275764; = p.L43M on NM_182489.2) | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); called by muse, mutect2
- TADA2B | c.898A>T p.T300S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- TCF15 | c.400del p.A134Pfs*53 | Frame Shift Del (DEL) | VAF 23/170 reads (14%) | called by mutect2, pindel, varscan2
- TCF21 | c.100T>A p.S34T | Missense Mutation (SNP) | VAF 26/574 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.112); called by muse, mutect2
- TENM1 | c.4670T>A p.L1557Q | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.07); called by muse, mutect2
- TGM5 | c.785T>A p.L262Q (on ENST00000220420 / NM_201631.4; = p.L180Q on NM_004245.4) | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TINAG | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- TNNI3 | c.373-4C>A | Splice Region (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- TNR | c.705C>G p.C235W | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM38 | c.172T>A p.C58S | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- TSGA10 | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, varscan2
- TSKU | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); called by muse, mutect2
- TSPAN19 | c.478A>C p.T160P | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TTN | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 18/195 reads (9%) | PolyPhen benign (0.009); called by muse, mutect2
- UPF2 | c.419T>A p.L140* | Nonsense Mutation (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- USH2A | c.6740C>A p.P2247H | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP17L1 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- USP24 | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UTP14C | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VCP | c.1694A>C p.K565T | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS13B | c.5991del p.K1998Rfs*21 | Frame Shift Del (DEL) | VAF 46/330 reads (14%) | called by mutect2, pindel*, varscan2
- VPS50 | c.2382G>C p.M794I | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2
- VWA5B1 | c.3425G>C p.G1142A (on ENST00000375079; = p.G1137A on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- VWC2 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.413); called by muse, mutect2
- WASF1 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); called by muse, mutect2
- WDFY4 | c.8137A>T p.M2713L | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2
- WDR87 | c.4928C>T p.T1643I | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.299); called by muse, mutect2
- WWC3 | c.2876_2879del p.A959Gfs*24 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- ZC3H6 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZFHX4 | c.4860G>T p.K1620N | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZNF227 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- ZNF235 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZNF43 | c.2185A>T p.T729S | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- ZNF735 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM2 | c.1338G>C p.Q446H | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- A1CF | c.1308T>A p.P436= (on ENST00000373993 / NM_138932.2; = p.P428= on NM_014576.4) | Silent (SNP) | VAF 22/245 reads (9%) | called by muse, mutect2
- ACSM5 | c.786C>A p.T262= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV59372901; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4350T>A p.A1450= | Silent (SNP) | VAF 49/350 reads (14%) | called by muse, mutect2, varscan2
- AHNAK2 | c.7956G>A p.K2652= | Silent (SNP) | VAF 71/317 reads (22%) | catalogued as rs1188464254; called by muse, mutect2, varscan2
- APCDD1L | c.345C>A p.A115= | Silent (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- APOBR | c.3162C>T p.T1054= (on ENST00000431282; = p.T1063= on NM_018690.4) | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- ATG2B | c.1041G>T p.G347= | Silent (SNP) | VAF 69/367 reads (19%) | called by muse, mutect2, varscan2
- BRWD3 | c.1884T>G p.G628= | Silent (SNP) | VAF 16/291 reads (5%) | called by muse, mutect2
- C10orf71 | c.2208C>T p.S736= | Silent (SNP) | VAF 30/301 reads (10%) | called by muse, mutect2
- CCN2 | c.237C>A p.G79= | Silent (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2
- CFAP69 | c.384G>C p.S128= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as COSV60185838; called by muse, mutect2, varscan2
- CLVS2 | c.360C>A p.V120= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- CSMD3 | c.10833G>T p.L3611= (on ENST00000297405 / NM_001363185.1; = p.L3442= on NM_052900.3) | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV52115126; called by muse, mutect2, varscan2
- CYP7A1 | c.729G>A p.R243= | Silent (SNP) | VAF 22/366 reads (6%) | catalogued as COSV56966175; called by muse, mutect2
- DDX60 | c.3099G>T p.L1033= | Silent (SNP) | VAF 19/207 reads (9%) | called by muse, mutect2
- DLG5 | c.2136G>T p.L712= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- DUSP26 | c.561C>T p.G187= | Silent (SNP) | VAF 6/131 reads (5%) | catalogued as rs1320887812, COSV56362430; called by muse, mutect2
- DYRK3 | c.378A>G p.T126= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as rs571191552; called by muse, varscan2
- ELAC2 | c.1050G>A p.V350= | Silent (SNP) | VAF 11/300 reads (4%) | called by muse, mutect2
- FANCM | c.3570C>G p.L1190= | Silent (SNP) | VAF 26/215 reads (12%) | catalogued as COSV57501546; called by muse, mutect2, varscan2
- FCRL3 | c.1323G>T p.L441= | Silent (SNP) | VAF 16/161 reads (10%) | called by muse, mutect2
- FGF3 | c.237G>A p.T79= | Silent (SNP) | VAF 28/293 reads (10%) | catalogued as rs376992420; called by muse, mutect2
- FIBP | c.877C>T p.L293= (on ENST00000338369 / NM_198897.2; = p.L286= on NM_004214.5) | Silent (SNP) | VAF 20/237 reads (8%) | catalogued as rs760517626, COSV57172892; called by muse, mutect2
- FPR3 | c.507T>C p.T169= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- GH2 | c.316C>T p.L106= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs757407010; called by muse, mutect2, varscan2
- GPR173 | c.945T>C p.C315= | Silent (SNP) | VAF 15/220 reads (7%) | catalogued as COSV60233468; called by muse, mutect2
- GRM5 | c.1779C>A p.A593= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV100554959; called by muse, mutect2
- GSTA2 | c.201G>A p.Q67= | Silent (SNP) | VAF 10/247 reads (4%) | called by muse, mutect2
- HNRNPU | c.1713A>T p.I571= (on ENST00000283179; = p.I633= on NM_004501.3) | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- LRRTM1 | c.417G>A p.L139= | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- MDM1 | c.687C>T p.I229= | Silent (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- MDN1 | c.3036A>G p.Q1012= | Silent (SNP) | VAF 17/321 reads (5%) | called by muse, mutect2
- MRGPRG | c.168C>T p.A56= | Silent (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- MROH8 | c.1731A>G p.L577= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- MUC5B | c.3603A>C p.P1201= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- NID1 | c.663C>T p.F221= | Silent (SNP) | VAF 21/273 reads (8%) | catalogued as rs368863123, COSV51619630; called by muse, mutect2
- NINL | c.2664G>T p.T888= | Silent (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- NLRP14 | c.1509T>A p.P503= | Silent (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- NRAP | c.2166C>G p.V722= (on ENST00000359988 / NM_001322945.2; = p.V687= on NM_006175.4) | Silent (SNP) | VAF 10/176 reads (6%) | catalogued as COSV63488630; called by muse, mutect2
- OPRM1 | c.792C>T p.V264= | Silent (SNP) | VAF 11/259 reads (4%) | catalogued as COSV57686194; called by muse, mutect2
- OR2AP1 | c.363T>C p.Y121= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV58726792; called by muse, mutect2, varscan2
- PCDHA11 | c.1233C>A p.A411= | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1236G>C p.R412= | Silent (SNP) | VAF 28/316 reads (9%) | catalogued as COSV54025241, COSV54051204; called by muse, mutect2
- PDE3A | c.2799C>A p.T933= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- PDZK1 | c.60T>C p.Y20= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, varscan2
- PHF14 | c.513C>G p.T171= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- PRDM9 | c.426A>T p.A142= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as COSV57009808; called by muse, mutect2
- PTK6 | c.573C>T p.F191= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- PXDNL | c.411A>G p.L137= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- RAB5A | c.498A>G p.T166= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs1167318350; called by muse, mutect2, varscan2
- RRP12 | c.963C>G p.G321= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- SACS | c.1998G>T p.L666= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- SLC17A7 | c.558A>G p.T186= | Silent (SNP) | VAF 17/196 reads (9%) | called by muse, mutect2
- SLITRK3 | c.1383C>G p.L461= | Silent (SNP) | VAF 17/267 reads (6%) | catalogued as COSV99580517; called by muse, mutect2
- SPATA16 | c.987A>T p.T329= | Silent (SNP) | VAF 16/290 reads (6%) | catalogued as rs1282929562; called by muse, mutect2
- SPHKAP | c.3471C>T p.S1157= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV60894630; called by muse, mutect2
- SRFBP1 | c.114G>T p.L38= | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- SSUH2 | c.672G>T p.L224= | Silent (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- TAP2 | c.1395G>A p.Q465= | Silent (SNP) | VAF 12/322 reads (4%) | catalogued as COSV66500062; called by muse, mutect2
- TBR1 | c.738C>A p.P246= | Silent (SNP) | VAF 8/210 reads (4%) | called by muse, mutect2
- TECTA | c.3774G>T p.L1258= | Silent (SNP) | VAF 9/217 reads (4%) | catalogued as COSV50764725; called by muse, mutect2
- TG | c.6648C>T p.I2216= | Silent (SNP) | VAF 26/312 reads (8%) | catalogued as COSV55095581; called by muse, mutect2
- TRIM49B | c.93G>A p.G31= | Silent (SNP) | VAF 18/318 reads (6%) | catalogued as rs1243749404; called by muse, mutect2
- TRPC4AP | c.756C>T p.T252= | Silent (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- TTN | c.35616A>G p.E11872= (on ENST00000591111; = p.E4448= on NM_003319.4) | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- USP21 | c.1356A>G p.V452= | Silent (SNP) | VAF 11/288 reads (4%) | catalogued as rs1333581784; called by muse, mutect2
- VHLL | c.207G>T p.V69= | Silent (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- ZIM3 | c.12C>A p.S4= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV54144666, COSV54146710; called by muse, mutect2
- ZNF19 | c.1128G>T p.L376= | Silent (SNP) | VAF 27/230 reads (12%) | called by muse, mutect2, varscan2
- ZNF804A | c.952T>C p.L318= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- AC024940.1 | n.2114G>T | RNA (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2
- AL358333.1 | chr14:51979309 C>A | 3'Flank (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2, varscan2
- ALG3 | c.-20A>G | 5'UTR (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- AMACR | c.739+1164G>T | Intron (SNP) | VAF 16/174 reads (9%) | catalogued as rs777411203; called by muse, mutect2
- ARHGEF1 | c.1121+71G>T | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- B3GAT3 | c.-22G>T | 5'UTR (SNP) | VAF 14/132 reads (11%) | catalogued as rs774066555, COSV99642166; called by muse, mutect2
- BPIFB6 | c.197+273T>A | Intron (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- CCDC107 | chr9:35657956 G>T | 5'Flank (SNP) | VAF 13/151 reads (9%) | called by muse, mutect2
- CCN6 | c.49-959G>T | Intron (SNP) | VAF 30/509 reads (6%) | called by muse, mutect2
- EMBP1 | n.831C>A | RNA (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- EP400 | c.2827+19A>T | Intron (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- FAM193A | c.-153C>T | 5'UTR (SNP) | VAF 14/164 reads (9%) | catalogued as rs772616627; called by muse, mutect2
- GCNT2 | c.925+27054C>T | Intron (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2
- GCNT7 | c.-290G>A | 5'UTR (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- GFPT2 | c.7+707G>T | Intron (SNP) | VAF 13/97 reads (13%) | catalogued as rs1458282835; called by muse, mutect2, varscan2
- GRAMD1B | c.1085-26A>G | Intron (SNP) | VAF 55/445 reads (12%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+7135G>T | Intron (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2
- LINC00840 | n.273G>T | RNA (SNP) | VAF 22/200 reads (11%) | called by muse, varscan2
- LINC01101 | n.502C>G | RNA (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- LYPD3 | c.383-147C>A | Intron (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- MANBAL | c.150+906A>G | Intron (SNP) | VAF 18/176 reads (10%) | called by muse, mutect2, varscan2
- MTCL1 | c.2967+125G>C | Intron (SNP) | VAF 24/544 reads (4%) | called by muse, mutect2
- MYO15A | c.9387-117C>T | Intron (SNP) | VAF 22/252 reads (9%) | catalogued as rs1162194591; called by muse, mutect2
- MYO7B | c.6250-141G>A | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as rs534308876; called by muse, mutect2, varscan2
- NUDCD3 | c.509+17027C>G | Intron (SNP) | VAF 10/338 reads (3%) | called by muse, mutect2
- OFCC1 | n.49C>G | RNA (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- OR51F5P | n.318C>T | RNA (SNP) | VAF 11/187 reads (6%) | catalogued as rs879205496; called by muse, mutect2
- PAGE4 | c.166+33C>A | Intron (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- PAX8 | c.777+107G>A | Intron (SNP) | VAF 13/204 reads (6%) | called by muse, mutect2
- PHF20L1 | c.1579+19del | Intron (DEL) | VAF 16/113 reads (14%) | catalogued as COSV55191680; called by mutect2, pindel, varscan2
- PLTP | c.-2C>A | 5'UTR (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- PUDP | c.511-7321G>T | Intron (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- RGS9 | c.655-29C>T | Intron (SNP) | VAF 28/244 reads (11%) | catalogued as rs1001386065; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611231 A>T | 5'Flank (SNP) | VAF 80/687 reads (12%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159437 ins T | 5'Flank (INS) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- S1PR3 | c.-148+153C>T | Intron (SNP) | VAF 34/388 reads (9%) | catalogued as rs370512317; called by muse, mutect2
- SH2D6 | n.500C>A | RNA (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- SIGLEC14 | c.701-18T>A | Intron (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- SLC6A19 | c.1017-26G>C | Intron (SNP) | VAF 17/270 reads (6%) | called by muse, mutect2
- SNORD52 | chr6:31837362 G>C | 3'Flank (SNP) | VAF 27/254 reads (11%) | called by muse, mutect2, varscan2
- SSX5 | c.70-199C>A | Intron (SNP) | VAF 14/254 reads (6%) | catalogued as COSV100308691; called by muse, mutect2
- SYNE1 | c.9651+11C>T | Intron (SNP) | VAF 15/146 reads (10%) | catalogued as rs762554940, COSV55058753; ClinVar: likely benign; called by mutect2, varscan2
- TAP1 | c.1747-48G>C | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- TIAM2 | c.2361+3475C>G | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- TMEM59L | c.664+275T>C | Intron (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- TMEM78 | n.166T>C | RNA (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2, varscan2
- UBBP4 | n.786G>T | RNA (SNP) | VAF 47/454 reads (10%) | called by muse, varscan2
- WT1 | chr11:32439624 T>C | 5'Flank (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- XAGE5 | c.*17G>T | 3'UTR (SNP) | VAF 13/184 reads (7%) | catalogued as COSV100657820; called by muse, mutect2
- Y_RNA | chr7:75516171 C>T | 5'Flank (SNP) | VAF 25/348 reads (7%) | called by muse, mutect2
- ZEB2 | chr2:144519941 G>T | 5'Flank (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
